Somatic mutation profile of tumor specimen TARGET-10-PANWYH-09A (aliquot TARGET-10-PANWYH-09A-01D) from TARGET case TARGET-10-PANWYH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,786 days).
Specimen TARGET-10-PANWYH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1724f615-6cac-4b82-a6a2-83461b64747e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANWYH-10A (Blood Derived Normal), aliquot TARGET-10-PANWYH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c5ba0f7-d73c-4484-b821-25c065705eb8

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Intron 4, Nonsense Mutation 2, Silent 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 63/212 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- C3 | c.3070G>A p.A1024T | Missense Mutation (SNP) | VAF 82/235 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as rs1421843172, COSV55577235; called by muse, mutect2, varscan2
- CUL7 | c.4058G>A p.S1353N | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54820119; called by muse, mutect2, varscan2
- FSCN2 | c.1314C>A p.S438R | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.061); catalogued as rs756328540; called by muse, varscan2
- GPR158 | c.3085G>A p.V1029I | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs770315576; called by muse, mutect2, varscan2
- TRAV22 | c.262C>A p.R88S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as rs771830762; called by muse, mutect2, varscan2
- ABCG1 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALPK3 | c.2566C>A p.P856T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.637); called by muse, mutect2
- CAMSAP1 | c.3250G>T p.V1084L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2
- ETV6 | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- FEM1A | c.658C>A p.L220I | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MED26 | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- MYO15A | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2
- ROBO1 | c.2974A>T p.I992F | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SLC7A11 | c.1178G>A p.S393N | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- SMCR8 | c.2163C>A p.H721Q | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- TTBK1 | c.3583C>T p.Q1195* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- TTYH3 | c.1108C>A p.H370N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZSWIM2 | c.1039T>A p.C347S | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNTNAP2 | c.2127C>A p.G709= | Silent (SNP) | VAF 66/212 reads (31%) | catalogued as rs762250248; called by muse, mutect2, varscan2
- BRD8 | c.788-76G>T | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- COL1A1 | chr17:50180919 ins G | 3'Flank (INS) | VAF 5/38 reads (13%) | catalogued as rs772461427; called by pindel, varscan2
- FRA10AC1 | c.827-2528G>C | Intron (SNP) | VAF 56/139 reads (40%) | called by muse, mutect2, varscan2
- KRT18 | c.417+73G>A | Intron (SNP) | VAF 118/396 reads (30%) | catalogued as rs776589260; called by muse, mutect2, varscan2
- NDUFA12 | c.170-45T>A | Intron (SNP) | VAF 8/118 reads (7%) | catalogued as rs1222247231; called by muse, mutect2
